Gene-level copy-number profile of tumor specimen TCGA-A6-2672-01B from TCGA case TCGA-A6-2672, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 82.8 years (30,237 days).
Specimen TCGA-A6-2672-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.622b0cb2-6c15-42f3-b3ec-eff97d63797c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-2672-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate.
https://portal.gdc.cancer.gov/files/5314533b-dc02-41e8-8cc5-283007313a05

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 81; copy number 2: 58,228; copy number 3: 1,391; copy number 4: 9; copy number 5: 18; copy number 7: 6; copy number 11: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-A6-2672-01): tumor purity 0.59, ploidy 2.07, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,247,205–155,262,430, 2 genes: FAM189B, SCAMP3.
- chr4:69,437,357–69,451,613, 2 genes: AC108078.3, AC108078.2.
- chr10:78,352,597–78,367,623, 2 genes (within-gene range 0–2): AC010163.2, SNORA71.
- chr12:130,024,493–130,044,956, 1 gene (within-gene range 0–2): AC055717.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,712,498, 6 genes, copy number 7: UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1.
- chr7:19,144,293–19,146,253, 2 genes, copy number 5: AC003986.1, FERD3L.
- chr9:19,895,800–19,929,937, 2 genes, copy number 5: AL158077.1, AL591222.1.
- chr9:94,809,962–94,824,773, 2 genes, copy number 5: MIR2278, AL807757.1.
- chr15:25,054,210–25,081,378, 14 genes, copy number 11: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.
- chr17:41,275,659–41,309,253, 4 genes, copy number 5: KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1.
- chr21:43,053,191–43,332,039, 8 genes, copy number 5: CBS, U2AF1, AP001631.2, MRPL51P2, FRGCA, AP001631.1, CRYAA, LINC00322.

Autosomal genes at a single copy (total copy number 1): 81. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
